Gene-level copy-number profile of tumor specimen TCGA-CV-7428-01A from TCGA case TCGA-CV-7428, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.7 years (17,429 days).
Specimen TCGA-CV-7428-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.73c12fc1-bd76-4b68-b367-2af3acc51154.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7428-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/c0650372-8468-4f5c-9ab4-f5ec46afffca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 530; copy number 1: 8,518; copy number 2: 46,668; copy number 3: 2,423; copy number 4: 1,966; copy number 5: 28; copy number 7: 25; copy number 11: 25; copy number 12: 11; copy number 16: 47; copy number 19: 31.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:184,431,966–184,432,049, 1 gene: SNORD79.
- chr8:39,309,909–39,522,852, 3 genes: AC105185.1, ADAM5, ADAM3A.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 167 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 7 (within-gene range 2–7): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 7: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr9:114,850,968–115,402,644, 1 gene, copy number 5 (within-gene range 4–5): DELEC1.
- chr9:115,019,575–117,466,260, 21 genes, copy number 5 (within-gene range 4–5): TNC, AL162425.1, AL355601.1, AL691420.1, U2, LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1, ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1.
- chr12:65,418,731–70,920,738, 114 genes, copy number 11–19 (within-gene range 1–19) (broad region; genes not listed).
- chr17:46,029,916–46,225,389, 1 gene, copy number 5 (within-gene range 2–5): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 5: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 6,101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
